CCDI case PBBVZC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/9c9b7f54-a8f1-48d9-9574-33eb39785b75

Demographics
Sex at birth: female; Race: white; Vital status: Dead.

Diagnoses (1)
1. Neoplasm, malignant: ICD-O-3 morphology code: 8000/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 2.2 years (813 days).

Biospecimens (3 samples)
- Sample 0DIPKQ: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DIPL0: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DIPLQ: Tissue type: Tumor; Specimen type: Solid Tissue.
